Somatic mutation profile of tumor specimen TCGA-VQ-A91E-01A (aliquot TCGA-VQ-A91E-01A-31D-A410-08) from TCGA case TCGA-VQ-A91E, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 67.2 years (24,549 days).
Specimen TCGA-VQ-A91E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7ab8b5b-d535-41a3-861f-b9f79fca9165.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91E-10A (Blood Derived Normal), aliquot TCGA-VQ-A91E-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6e4d3c1-a96e-47c4-ae40-02d701f55c29

The open-access MAF lists 892 somatic variants for this specimen: 696 protein-altering or splice-affecting, 181 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 449, Silent 181, Frame Shift Del 174, Nonsense Mutation 25, Frame Shift Ins 19, Splice Site 13, Splice Region 10, Intron 8, In Frame Del 4, RNA 3, 3'Flank 1, 3'UTR 1.

Variants (750 of 892; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141677867, CM105798, COSV99710562; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DSG2 | c.2533del p.I845* | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as rs1375081885; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KCNA1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28933383, CM076245, CM962692, CM993940, COSV66836391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.5824del p.R1942Afs*7 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1567195285, CM1513823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTCH1 | c.290del p.N97Tfs*20 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs1554708751, CD066395, CX962597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 4/45 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCF3 | c.1392-2A>G p.X464_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as rs41266255, COSV99491485; called by muse, varscan2
- ACBD5 | c.1192G>A p.G398R (on ENST00000375888 / NM_001352568.1; = p.G389R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as rs759217853, COSV101022558, COSV65519976; called by muse, mutect2
- ACCSL | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.364); catalogued as COSV101122204; called by muse, mutect2, varscan2
- ACP5 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs774878498, COSV54537782; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACY3 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99663024; called by muse, mutect2, varscan2
- ADAD1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs766007013, COSV56643265; called by muse, mutect2, varscan2
- ADAM2 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761884012, COSV55870337, COSV99697056; called by muse, mutect2, varscan2
- ADAMTS18 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV99273024; called by muse, mutect2, varscan2
- ADGRA1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs199841510, COSV66925412; called by muse, mutect2, varscan2
- AFF2 | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650255; called by muse, mutect2, varscan2
- AFF3 | c.1571A>G p.K524R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as COSV100419144; called by muse, mutect2, varscan2
- AGO1 | c.1966C>A p.R656S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); catalogued as COSV100940856; called by muse, mutect2, varscan2
- AGO4 | c.203T>C p.M68T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100942979; called by muse, mutect2, varscan2
- AHI1 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99662909; called by muse, mutect2, varscan2
- AKAP12 | c.5273C>T p.A1758V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1199158538, COSV99483495; called by muse, mutect2, varscan2
- AKAP6 | c.5150C>T p.S1717L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs146242099; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALAS1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100050135, COSV100050357; called by muse, mutect2, varscan2
- ALAS1 | c.1684A>G p.T562A | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050358; called by muse, mutect2, varscan2
- ALDOC | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs201657122, COSV52025681; called by muse, mutect2, varscan2
- ALMS1 | c.10775C>G p.T3592S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as COSV100042653; called by muse, mutect2
- ALPK1 | c.175T>C p.W59R | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99454245; called by muse, mutect2
- ALPK3 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.906); catalogued as COSV99361057; called by muse, mutect2
- ALPK3 | c.4262G>A p.R1421Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs770717324, COSV99361059; called by muse, mutect2, varscan2
- AMBRA1 | c.2728A>C p.S910R (on ENST00000458649 / NM_001367468.1; = p.S820R on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as COSV100094202; called by muse, mutect2, varscan2
- ANK3 | c.2764T>C p.S922P (on ENST00000280772 / NM_001320874.2; = p.S56P on NM_001149.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99780307; called by muse, mutect2, varscan2
- ANKRD50 | c.1262G>A p.C421Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101538973; called by muse, mutect2, varscan2
- ANKRD55 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100591407; called by muse, mutect2, varscan2
- ANO5 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); catalogued as COSV100201913, COSV61088531; called by muse, mutect2
- AP3D1 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1171181587, COSV100642739; called by muse, mutect2, varscan2
- AP3M2 | c.584-2A>G p.X195_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51527726; called by muse, varscan2
- AP5Z1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs566001734, COSV62241071; called by muse, mutect2, varscan2
- APCDD1 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100789972; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs749401724; called by mutect2, varscan2
- ARFGEF2 | c.2098A>G p.S700G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100904292; called by muse, mutect2, varscan2
- ARHGEF10 | c.4021C>T p.R1341C (on ENST00000398564; = p.R1316C on NM_014629.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs756018244, COSV50644885; called by muse, mutect2, varscan2
- ARHGEF37 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs775287566, COSV100382142; called by muse, mutect2, varscan2
- ARHGEF7 | c.2030C>A p.P677H (on ENST00000375741 / NM_001113511.2; = p.P499H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521615; called by muse, mutect2
- ARID1A | c.5918G>A p.W1973* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV61370591; called by muse, mutect2, varscan2
- ARID5B | c.2901dup p.Y968Ifs*3 | Frame Shift Ins (INS) | VAF 13/91 reads (14%) | catalogued as rs375905946; called by mutect2, pindel, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs761154268; called by mutect2, varscan2
- ASXL2 | c.2773A>G p.S925G | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99711259; called by muse, mutect2, varscan2
- ATG101 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100401042; called by muse, mutect2, varscan2
- ATM | c.7444A>G p.M2482V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs951373716, COSV99589888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP5F1B | c.951+2T>C p.X317_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100008127; called by muse, mutect2, varscan2
- ATP5MF | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as rs761746638, COSV99461762; called by muse, mutect2, varscan2
- ATXN1 | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1395417495, COSV99786655; called by muse, mutect2, varscan2
- ATXN7 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99894559; called by muse, mutect2, varscan2
- AVP | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100977779; called by muse, mutect2, varscan2
- AVPR1A | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV54546979; called by muse, mutect2
- B3GNT3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV100592759; called by mutect2, varscan2
- B4GAT1 | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1489316157, COSV100240285; called by muse, mutect2, varscan2
- BACH1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99728319; called by muse, mutect2, varscan2
- BAG3 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1197677178, COSV100958242; called by muse, mutect2, varscan2
- BAG6 | c.2561C>T p.T854M (on ENST00000676571; = p.T807M on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs780710425, COSV52990495; called by muse, mutect2, varscan2
- BBS5 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99751979; called by muse, mutect2, varscan2
- BCORL1 | c.2641G>A p.V881M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs746950692, COSV99498307; called by muse, mutect2, varscan2
- BCS1L | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99829040; called by muse, mutect2, varscan2
- BIN3 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as COSV99374080; called by muse, mutect2
- BIRC6 | c.7232T>C p.M2411T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101428351; called by muse, varscan2
- BOD1L1 | c.2600G>A p.R867K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99239500; called by muse, mutect2, varscan2
- BRINP3 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV100818903, COSV66527387; called by muse, mutect2, varscan2
- BRWD3 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs866592729, COSV64746272; called by muse, mutect2, varscan2
- BTBD16 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs149204272; called by muse, mutect2, varscan2
- BTK | c.1780G>T p.G594W | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM002246, CM950176, COSV100437636; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C15orf39 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759535804, COSV100641362; called by muse, mutect2
- C1orf158 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as COSV99847323; called by muse, mutect2, varscan2
- C8A | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs530776774, COSV100776515; called by muse, mutect2, varscan2
- CACNA1S | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as rs767052156, COSV62938565; called by muse, mutect2, varscan2
- CACNA2D4 | c.2159A>G p.E720G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV54946146; called by muse, mutect2
- CADPS2 | c.905A>C p.E302A | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100463247; called by muse, mutect2
- CALCOCO1 | c.850-2A>G p.X284_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100017358; called by muse, mutect2
- CARD11 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as COSV101210749; called by muse, mutect2, varscan2
- CARMIL2 | c.2867T>C p.L956P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99537753; called by muse, mutect2, varscan2
- CAV2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99760802; called by muse, mutect2, varscan2
- CBLN1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); catalogued as COSV99535700; called by muse, mutect2, varscan2
- CCDC178 | c.1662dup p.L555Tfs*11 | Frame Shift Ins (INS) | VAF 10/61 reads (16%) | catalogued as rs753180261; called by mutect2, pindel, varscan2
- CCDC178 | c.1365del p.K455Nfs*9 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs771120201; called by mutect2, pindel, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC62 | c.2036del p.N679Ifs*18 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | catalogued as rs1053262354; called by mutect2, pindel, varscan2
- CCDC66 | c.1888G>T p.G630* (on ENST00000394672 / NM_001353147.1; = p.G596* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100414026; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs762553129; called by mutect2, varscan2
- CCNB3 | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs201488068, COSV52074602; called by muse, mutect2, varscan2
- CCP110 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101195289; called by muse, mutect2, varscan2
- CCT2 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs746543261, COSV100167670; called by mutect2, varscan2
- CD22 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as rs758916954, COSV50050362; called by muse, varscan2
- CD5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs759626085, COSV61718127, COSV61719234; called by mutect2, varscan2
- CD96 | c.724G>T p.G242W (on ENST00000283285 / NM_198196.3; = p.G226W on NM_005816.5) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99342969; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH11 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV51758168, COSV99218106; called by muse, mutect2, varscan2
- CDH8 | c.578A>C p.D193A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181961; called by muse, mutect2, varscan2
- CDHR4 | c.139T>C p.Y47H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV58526127; called by muse, mutect2
- CDK19 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV100098666; called by muse, mutect2
- CDKAL1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1027656765, COSV51186943, COSV99215607; called by muse, mutect2, varscan2
- CELF1 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV100136964; called by muse, mutect2, varscan2
- CELSR3 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs754864877, COSV99373719; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP45 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs774638004, COSV63651663; called by muse, mutect2, varscan2
- CFAP52 | c.854+2T>C p.X285_splice | Splice Site (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100235273; called by muse, mutect2
- CFAP65 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200117910; called by mutect2, varscan2
- CHAT | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.52); catalogued as rs202125860, COSV60320297, COSV60334492; called by mutect2, varscan2
- CHCHD6 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as rs1379947664, COSV99336418; called by muse, mutect2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- CHD4 | c.1203C>T p.C401= (on ENST00000357008 / NM_001363606.2; = p.C414= on NM_001273.5) | Splice Region (SNP) | VAF 13/67 reads (19%) | catalogued as rs761570351, COSV58906589; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD5 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.233); catalogued as rs146062488; called by mutect2, varscan2
- CHD6 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV100498342; called by muse, mutect2, varscan2
- CHGB | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100972974; called by muse, mutect2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CHSY3 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519268; called by muse, mutect2, varscan2
- CLCN6 | c.373T>C p.C125R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.467); catalogued as COSV100411975; called by muse, mutect2, varscan2
- CMYA5 | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101484121; called by muse, mutect2, varscan2
- CNKSR2 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99668759; called by muse, mutect2, varscan2
- CNTLN | c.438G>T p.L146F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99264360; called by muse, mutect2, varscan2
- COG3 | c.1188T>C p.D396= | Splice Region (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100596542; called by muse, mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV100615079, COSV62186140; called by pindel, varscan2
- COL16A1 | c.3418C>T p.R1140* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs770009606, COSV99594614; called by muse, mutect2, varscan2
- COL5A3 | c.1373del p.P458Qfs*20 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV53417817; called by mutect2, pindel
- COL7A1 | c.5296G>A p.A1766T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.286); catalogued as COSV100096433; called by muse, mutect2
- CORIN | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs140958503; called by muse, mutect2, varscan2
- CPNE3 | c.778del p.S260Afs*10 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs761955273; called by mutect2, pindel, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRX | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778203784, COSV99704529; called by muse, mutect2, varscan2
- CSMD3 | c.4915T>C p.Y1639H (on ENST00000297405 / NM_001363185.1; = p.Y1535H on NM_052900.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99829062, COSV99836234; called by muse, mutect2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTR9 | c.3220C>T p.R1074W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs202230543, COSV100797379; called by muse, mutect2, varscan2
- CUL9 | c.2815C>A p.P939T | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV99335488; called by muse, mutect2, varscan2
- CYBRD1 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs1427721375, COSV100361354; called by muse, mutect2
- CYFIP2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as COSV100557044; called by muse, mutect2
- CYP2U1 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100256717; called by muse, varscan2
- CYP7B1 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100042030; called by muse, mutect2, varscan2
- DBN1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as rs201033708, COSV52793692; called by muse, mutect2, varscan2
- DCAF12L2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1047080686, COSV63580676, COSV63584176; called by muse, mutect2, varscan2
- DDX3X | c.91A>C p.S31R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.499); catalogued as COSV101302450; called by muse, mutect2, varscan2
- DDX47 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs775095603, COSV61911792; called by muse, mutect2
- DDX59 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as rs759640859, COSV100494567; called by muse, mutect2, varscan2
- DEDD | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV100919098; called by muse, mutect2, varscan2
- DHX38 | c.1549A>C p.S517R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99194338; called by muse, mutect2, varscan2
- DICER1 | c.3988T>C p.Y1330H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV100602165; called by muse, mutect2, varscan2
- DISP1 | c.1825T>C p.F609L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.456); catalogued as COSV52654714; called by muse, mutect2, varscan2
- DLGAP2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192026977, COSV101421549; called by muse, mutect2, varscan2
- DLL1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV100816095, COSV64538129; called by muse, mutect2, varscan2
- DMD | c.2972A>C p.E991A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100820079; called by muse, mutect2, varscan2
- DMXL2 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761923802, COSV51847389; called by muse, mutect2, varscan2
- DNAAF1 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100533696; called by muse, mutect2, varscan2
- DNAH6 | c.2189A>G p.Y730C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99407009; called by muse, mutect2, varscan2
- DNAJC13 | c.3338A>G p.N1113S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99607400; called by muse, mutect2, varscan2
- DOCK11 | c.2135A>G p.D712G | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99353975; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPY19L2 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV100193520; called by muse, mutect2, varscan2
- DPYSL4 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100062658; called by muse, mutect2, varscan2
- DSC1 | c.1319C>A p.A440E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99937718; called by muse, mutect2, varscan2
- DSC1 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761035986, COSV57148617; called by muse, mutect2, varscan2
- DSE | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs370430595; called by mutect2, varscan2
- DST | c.2226T>C p.A742= (on ENST00000361203 / NM_001374722.1; = p.A416= on NM_001723.6) | Splice Region (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99756836; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs746928635; called by mutect2, pindel
- DYM | c.112_113del p.S38Ifs*8 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | catalogued as rs766687175; called by pindel, varscan2
- DYNC2H1 | c.6928T>C p.S2310P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100518732, COSV100520240; called by muse, mutect2, varscan2
- E2F8 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1292589519, COSV51463075; called by muse, mutect2
- EDEM3 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100545377; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1223A>G p.K408R (on ENST00000361735 / NM_015935.5; = p.K322R on NM_014955.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100675883; called by muse, mutect2, varscan2
- EEF2 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500798; called by muse, mutect2, varscan2
- EGF | c.2648del p.P883Lfs*67 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs758373637; called by mutect2, pindel, varscan2
- EIF4B | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as rs374172229; called by muse, mutect2, varscan2
- EIF4B | c.1664A>G p.H555R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.622); catalogued as COSV100016832; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs766177443, COSV100349195; called by muse, mutect2, varscan2
- EIF4G1 | c.3202C>T p.R1068* (on ENST00000346169 / NM_198241.3; = p.R873* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as COSV59994559; called by muse, mutect2
- EIF5B | c.293del p.K98Rfs*83 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs769971529; called by mutect2, varscan2
- EMILIN2 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as rs763050616, COSV54421478; called by mutect2, varscan2
- ENO3 | c.1099del p.V367* | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs961001512; called by mutect2, pindel, varscan2
- ENTPD4 | c.1720G>T p.V574L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100652667; called by muse, varscan2
- ENTR1 | c.983A>C p.E328A (on ENST00000357365 / NM_001039707.2; = p.E305A on NM_006643.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100048205; called by muse, mutect2, varscan2
- EPB41L5 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as rs777100198, COSV99758784; called by muse, mutect2, varscan2
- EPHA4 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99916698; called by muse, mutect2, varscan2
- EPHA7 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100992404; called by muse, mutect2, varscan2
- EPHB1 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs186851943, COSV67654218; called by muse, mutect2
- EPHX2 | c.346+2T>C p.X116_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100994613; called by muse, mutect2, varscan2
- ERAP1 | c.380del p.R127Lfs*48 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as CM094298, COSV57088529, COSV57091247; called by mutect2, pindel, varscan2
- ERN1 | c.1571G>A p.S524N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as COSV101458461; called by muse, mutect2
- ESR2 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs576722274, COSV99963339; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs775950025; called by mutect2, varscan2
- ETFB | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770414295, COSV58537848; called by muse, mutect2, varscan2
- EXTL3 | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99594045; called by muse, mutect2, varscan2
- FAM169A | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.602); catalogued as COSV100998359; called by muse, mutect2
- FAM210A | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs373098318; called by muse, mutect2, varscan2
- FAM98A | c.1464T>A p.Y488* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV99479326; called by muse, mutect2, varscan2
- FANCA | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101224859; called by muse, varscan2
- FAP | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV51864103; called by muse, mutect2, varscan2
- FBN1 | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV100355320; called by muse, mutect2, varscan2
- FBP2 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777645239, COSV100942145; called by muse, mutect2, varscan2
- FBXO24 | c.1033del p.L345Wfs*45 (on ENST00000241071 / NM_033506.3; = p.L383Wfs*45 on NM_012172.5) | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs1236194155; called by pindel, varscan2
- FCGR2A | c.308C>T p.T103M (on ENST00000271450 / NM_001136219.3; = p.T102M on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs368359610; called by muse, mutect2, varscan2
- FGA | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV100120431; called by muse, mutect2, varscan2
- FGF9 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV101210985; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs144178676; called by mutect2, varscan2
- FHL2 | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100363014; called by muse, mutect2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs777980924; called by mutect2, varscan2
- FIGN | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.74); catalogued as rs200358782, COSV100292340, COSV60763026; called by muse, mutect2, varscan2
- FJX1 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.278); catalogued as COSV100502686; called by muse, mutect2, varscan2
- FLG | c.2279A>G p.Q760R | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV64243921; called by muse, mutect2, varscan2
- FLNB | c.6862C>T p.R2288C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs765247131, COSV99913463; called by muse, mutect2, varscan2
- FMNL3 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752076456, COSV99526407; called by muse, mutect2, varscan2
- FMR1 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV99503351; called by muse, mutect2
- FN1 | c.2870G>A p.S957N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100117291; called by muse, mutect2, varscan2
- FOXB2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761676772, COSV100942349; called by muse, mutect2, varscan2
- FOXD3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs200810432, COSV100942796; called by muse, mutect2
- FOXP2 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as COSV100646796; called by muse, mutect2, varscan2
- FRAS1 | c.4939A>G p.T1647A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99352691; called by muse, mutect2
- FXYD7 | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV99544898; called by muse, mutect2, varscan2
- GALNT15 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs370556963; called by mutect2, varscan2
- GAR1 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV99901922; called by muse, mutect2, varscan2
- GCNT1 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs1407463600, COSV100946569; called by muse, mutect2, varscan2
- GIMAP5 | c.890del p.F297Sfs*30 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs774162620, COSV57529761, COSV57529909; called by mutect2, pindel, varscan2
- GJA8 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202852786, COSV53788305, COSV53788867; called by muse, mutect2, varscan2
- GK5 | c.815T>C p.L272S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV101242226; called by muse, mutect2
- GKN2 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV100187829; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel
- GON4L | c.6272C>T p.T2091M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs766751715, COSV99674541; called by muse, mutect2, varscan2
- GOT1 | c.1153A>G p.S385G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100763886; called by muse, mutect2
- GPR27 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55204949; called by muse, mutect2, varscan2
- GPR50 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as COSV99506219; called by muse, mutect2, varscan2
- GRAMD1A | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.177); catalogued as rs780284522, COSV100526208; called by mutect2, varscan2
- GRHL2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); catalogued as rs780540983, COSV99307071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIA3 | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99990450; called by muse, mutect2, varscan2
- GRID1 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60017779; called by muse, mutect2
- GRM5 | c.2184A>C p.E728D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100552321; called by muse, mutect2, varscan2
- GTF3C2 | c.1250T>C p.L417P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99272840; called by muse, mutect2, varscan2
- GTPBP6 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100397775; called by muse, mutect2, varscan2
- H2BC7 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs772306298; called by pindel, varscan2
- HCN2 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV52112994; called by muse, mutect2, varscan2
- HDAC4 | c.2415G>T p.E805D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.105); catalogued as COSV100613624; called by muse, mutect2, varscan2
- HEATR1 | c.3940A>G p.I1314V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1362499111, COSV100857656; called by muse, mutect2, varscan2
- HEATR1 | c.2386T>A p.F796I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs746366377, COSV100857657; called by muse, mutect2, varscan2
- HECW1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777261023, COSV67826494; called by muse, mutect2, varscan2
- HERC4 | c.1544T>C p.L515P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99517065; called by muse, mutect2, varscan2
- HHIPL1 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100415171; called by muse, mutect2, varscan2
- HIP1 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs138838220, COSV61183378; called by muse, mutect2, varscan2
- HK1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs1159752232, COSV100066853; called by muse, mutect2
- HOOK3 | c.1625T>A p.V542D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.175); catalogued as COSV100295538; called by muse, mutect2
- HOXB5 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99494559; called by muse, mutect2, varscan2
- HTR6 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200329647, COSV57033044; called by muse, mutect2, varscan2
- HUS1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as COSV99346506; called by muse, mutect2
- HYOU1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as COSV101345617; called by muse, mutect2, varscan2
- IDO2 | c.1200G>T p.E400D (on ENST00000389060; = p.E413D on NM_194294.2) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV100584785; called by muse, mutect2, varscan2
- IGFBP5 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.276); catalogued as rs758117726, COSV52082139; called by muse, mutect2, varscan2
- IGSF1 | c.3257A>C p.Q1086P | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100812121; called by muse, mutect2, varscan2
- IGSF10 | c.7711T>C p.S2571P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs763969322, COSV99180541; called by muse, mutect2, varscan2
- IGSF9B | c.2480T>C p.I827T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV100317795; called by muse, mutect2, varscan2
- ILDR2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99613597; called by muse, mutect2, varscan2
- ILRUN | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100927241; called by muse, mutect2, varscan2
- INTS4 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.827); catalogued as COSV101417208; called by muse, mutect2
- IRAK3 | c.803T>A p.I268N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99706236; called by muse, mutect2, varscan2
- IRS1 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100524616; called by muse, mutect2, varscan2
- ITCH | c.990T>C p.P330= (on ENST00000262650 / NM_001257137.3; = p.P289= on NM_031483.7 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 5/39 reads (13%) | catalogued as COSV52932212; called by muse, mutect2, varscan2
- ITGA9 | c.2788-1G>T p.X930_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99292927; called by muse, mutect2
- ITGB4 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772790459, COSV99564136; called by muse, mutect2, varscan2
- ITGB4 | c.5428A>G p.T1810A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs757045931, COSV99564141; called by mutect2, varscan2
- ITPR3 | c.5113del p.D1705Tfs*6 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs753781307; called by mutect2, pindel, varscan2
- ITPRIP | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.566); catalogued as rs537256083, COSV99532599; called by muse, mutect2, varscan2
- JADE1 | c.1753A>G p.T585A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99885884; called by muse, mutect2, varscan2
- KBTBD7 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs138237266; called by mutect2, varscan2
- KCNA1 | c.92A>T p.D31V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101230282, COSV66838705; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNK10 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.57); catalogued as rs755297136, COSV56642436; called by muse, mutect2, varscan2
- KCNN3 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99678455; called by muse, mutect2, varscan2
- KDM5B | c.2783T>C p.L928P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99350728; called by muse, mutect2, varscan2
- KIAA1210 | c.3127G>C p.G1043R | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101274219; called by muse, mutect2, varscan2
- KIDINS220 | c.1969C>T p.L657F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs377758428; called by muse, mutect2, varscan2
- KIF17 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762499616, COSV99929164; called by muse, mutect2, varscan2
- KIF7 | c.1702dup p.L568Pfs*21 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | catalogued as rs772716663; called by mutect2, pindel, varscan2
- KIFBP | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs1481458834, COSV100741389; called by muse, mutect2, varscan2
- KIFC3 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1555607863, COSV65550924; called by muse, mutect2, varscan2
- KMT2D | c.10240A>G p.K3414E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV99982600; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs764099275; called by mutect2, varscan2
- KRT23 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs370055839; called by muse, mutect2, varscan2
- KRT33A | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50365354; called by muse, mutect2, varscan2
- KRT37 | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1203844987, COSV99845524; called by muse, mutect2
- KRTAP6-3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/34 reads (18%) | PolyPhen benign (0); catalogued as COSV101196489; called by muse, mutect2
- KSR2 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs531883128, COSV56666669, COSV56685840; called by muse, mutect2, varscan2
- LAMA1 | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs762641681, COSV101056591, COSV67544778; called by muse, mutect2, varscan2
- LAMA2 | c.8839A>G p.T2947A | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV101370519; called by muse, mutect2, varscan2
- LCT | c.5746C>T p.R1916* | Nonsense Mutation (SNP) | VAF 41/250 reads (16%) | catalogued as rs369141275, COSV99739252; called by muse, mutect2, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LLGL1 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100375426; called by muse, mutect2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 14/92 reads (15%) | catalogued as rs765287063; called by mutect2, varscan2
- LMBRD1 | c.970C>T p.R324C (on ENST00000649011; = p.R302C on NM_018368.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376456203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMX1A | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758502343, COSV99672425, COSV99672905; called by muse, mutect2, varscan2
- LMX1A | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376967723; called by muse, mutect2, varscan2
- LRP12 | c.2481G>T p.E827D | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99407820; called by muse, mutect2, varscan2
- LRP1B | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101257728; called by muse, mutect2, varscan2
- LRP5 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs748395267, COSV53714552; called by muse, mutect2, varscan2
- LRRC4B | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65349492; called by muse, mutect2, varscan2
- LRRC8D | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757148100, COSV100487316; called by muse, mutect2, varscan2
- LRRN3 | c.1979G>A p.S660N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1261066447, COSV100071125; called by muse, mutect2, varscan2
- LSM14A | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV101471702; called by muse, mutect2
- LSR | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100670477; called by muse, mutect2, varscan2
- MAGEA6 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs782740130, COSV100262850, COSV61449089; called by muse, mutect2, varscan2
- MAP3K21 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV100786279; called by muse, mutect2
- MAPK1 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV53186330, COSV99308013; called by muse, mutect2, varscan2
- MAPK1IP1L | c.493A>G p.N165D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV101133308; called by muse, mutect2, varscan2
- MAPKBP1 | c.3481del p.Q1161Sfs*174 (on ENST00000456763 / NM_001128608.2; = p.Q1155Sfs*174 on NM_014994.3) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV52966162; called by mutect2, pindel
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | catalogued as rs746267361; called by mutect2, varscan2
- MBTPS1 | c.859T>G p.S287A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100597633; called by muse, mutect2, varscan2
- MC1R | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs371458749; called by muse, mutect2, varscan2
- MCAM | c.1644A>C p.T548= | Splice Region (SNP) | VAF 18/116 reads (16%) | catalogued as COSV99876417; called by muse, mutect2, varscan2
- MCEMP1 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100365383; called by muse, mutect2
- MCM6 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773959284, COSV51469417; called by muse, mutect2, varscan2
- MDC1 | c.4169G>A p.R1390Q | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747316218, COSV64523921; called by muse, mutect2, varscan2
- MDM4 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs978267601, COSV100914460; called by muse, mutect2, varscan2
- MEPCE | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV99440098; called by muse, mutect2, varscan2
- MLEC | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57330556; called by muse, mutect2, varscan2
- MORC3 | c.2193A>G p.I731M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV101264945; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575130429, COSV100186855; called by muse, mutect2
- MPP6 | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99757560; called by muse, mutect2
- MRPL10 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764591801, COSV99270435; called by muse, mutect2, varscan2
- MRPL22 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as rs1355096459, COSV54559000; called by muse, mutect2, varscan2
- MSL2 | c.1365del p.K455Nfs*37 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | catalogued as COSV53859319; called by mutect2, pindel
- MTMR1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs782762145, COSV100953041, COSV100953157; called by muse, mutect2, varscan2
- MTMR14 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV56003963, COSV99931332; called by muse, mutect2, varscan2
- MTMR9 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325321359, COSV55312289; called by muse, mutect2
- MUC16 | c.20767A>G p.M6923V | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1366664204, COSV101200091; called by muse, mutect2, varscan2
- MUC16 | c.17693C>A p.P5898Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as COSV101200092; called by muse, mutect2, varscan2
- MXRA5 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs151002194, COSV54237455, COSV54246806; called by muse, mutect2, varscan2
- MYBPC3 | c.3755T>C p.V1252A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99920469; called by muse, mutect2, varscan2
- MYBPH | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs374800965; called by muse, mutect2, varscan2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs752868848; called by mutect2, pindel, varscan2
- MYO18B | c.6286A>G p.S2096G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV100123857; called by muse, mutect2, varscan2
- MYO1H | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs1361761912, COSV100183624; called by muse, mutect2, varscan2
- MYORG | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as rs1454379408, COSV52628872; called by muse, varscan2
- MYORG | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99898656; called by muse, varscan2
- NET1 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100742301; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 52/134 reads (39%) | catalogued as rs752284115; called by mutect2, varscan2
- NEXMIF | c.3157C>A p.L1053M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50127161, COSV99280969; called by muse, mutect2, varscan2
- NIBAN2 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100964903; called by muse, mutect2, varscan2
- NID1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs759141799, COSV51618836; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NPC1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99341411; called by muse, mutect2, varscan2
- NPNT | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as COSV99975169; called by muse, mutect2, varscan2
- NRG1 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55158291; called by muse, mutect2, varscan2
- NRP2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1448721197, COSV99784736; called by muse, mutect2, varscan2
- NRP2 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV99784740; called by mutect2, varscan2
- NSD3 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs991823454, COSV100395356; called by muse, mutect2, varscan2
- NSMCE3 | c.679T>G p.F227V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99722298; called by muse, mutect2, varscan2
- NTAN1 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV99816946; called by muse, mutect2, varscan2
- NTSR1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764154462, COSV65138432; called by muse, mutect2, varscan2
- NUCKS1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 26/200 reads (13%) | catalogued as COSV100900744; called by muse, mutect2, varscan2
- NUP155 | c.1748G>T p.R583I (on ENST00000231498 / NM_153485.3; = p.R524I on NM_004298.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV99193035; called by muse, mutect2, varscan2
- NUP205 | c.3771+2T>C p.X1257_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99607077; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- NUP214 | c.1715T>C p.M572T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100845303; called by mutect2, varscan2
- OBSCN | c.20476C>A p.L6826M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV100804090; called by muse, mutect2
- OR10A4 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101139523, COSV65842653; called by muse, mutect2, varscan2
- OR1B1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs370410299; called by mutect2, varscan2
- OR51G1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100429263; called by muse, mutect2, varscan2
- OR56A1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs779071207, COSV57362062, COSV57363619; called by mutect2, varscan2
- OR56A3 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100290254; called by muse, mutect2, varscan2
- OR5T3 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.19); catalogued as COSV100282824; called by muse, mutect2, varscan2
- OR6F1 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.084); catalogued as COSV100129235; called by muse, mutect2
- OSBPL2 | c.1225C>T p.R409C (on ENST00000313733 / NM_144498.4; = p.R397C on NM_014835.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs773593916, COSV100569373, COSV58218898; called by muse, mutect2, varscan2
- OTUD3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV100909026, COSV64296366; called by muse, mutect2
- OXCT2 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100560285; called by muse, mutect2, varscan2
- P2RX2 | c.295G>A p.V99M (on ENST00000343948 / NM_170683.4; = p.R76H on NM_012226.5) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100266956; called by muse, mutect2
- PAK1 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99583535; called by muse, mutect2, varscan2
- PAQR9 | c.896T>A p.I299N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100503819; called by muse, mutect2, varscan2
- PARD3B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs903715446, COSV100593715; called by muse, mutect2, varscan2
- PARN | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.473); catalogued as COSV100421039; called by muse, mutect2, varscan2
- PCBP3 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101234318; called by mutect2, varscan2
- PCDH15 | c.2000C>T p.T667M | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs143090687, COSV57419962; called by muse, mutect2, varscan2
- PCDH18 | c.248A>T p.N83I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100787349; called by muse, mutect2, varscan2
- PCDHB1 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1554267502, COSV60632265; called by muse, mutect2, varscan2
- PCDHB2 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as COSV99165355; called by muse, mutect2
- PCM1 | c.3454T>C p.F1152L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100279158; called by muse, varscan2
- PCNX1 | c.4973G>A p.S1658N | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV99455865; called by muse, mutect2, varscan2
- PDE1C | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs760282457, COSV58513096; called by muse, mutect2, varscan2
- PHKB | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV100067344; called by muse, mutect2, varscan2
- PHRF1 | c.1435G>A p.V479I (on ENST00000264555 / NM_001286581.2; = p.V478I on NM_020901.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs749704896, COSV99201009; called by muse, mutect2
- PIAS1 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1437669800, COSV99986838; called by muse, mutect2, varscan2
- PKD1L1 | c.2881G>T p.G961C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56973296; called by muse, mutect2, varscan2
- PKDREJ | c.5902T>C p.Y1968H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1366696798, COSV99478993; called by muse, mutect2, varscan2
- PLA2G2D | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs1329675570, COSV100908026; called by muse, mutect2, varscan2
- PLAGL2 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.905); catalogued as COSV99867309; called by muse, mutect2
- PLEC | c.11086A>G p.T3696A (on ENST00000322810 / NM_201380.4; = p.T3586A on NM_000445.5) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs782559387, COSV100514955; called by muse, mutect2, varscan2
- PLEC | c.9146C>T p.A3049V (on ENST00000322810 / NM_201380.4; = p.A2939V on NM_000445.5) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs935096656, COSV59705934; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PLEKHG3 | c.2180C>T p.S727L (on ENST00000394691; = p.S783L on NM_001308147.2) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs1199237564, COSV99906667; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLIN5 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.336); catalogued as COSV101113544; called by muse, mutect2, varscan2
- PLPP7 | c.292del p.V98Cfs*37 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as rs1398429355; called by mutect2, pindel, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PNMA5 | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100721648, COSV100721656; called by muse, mutect2, varscan2
- POLD1 | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101486879, COSV70955699; called by muse, mutect2
- POLR1A | c.4909G>A p.D1637N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs193068975, COSV99807805; called by muse, mutect2, varscan2
- POTEH | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs772083514, COSV58879904; called by muse, varscan2
- PPM1F | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99601517; called by muse, mutect2, varscan2
- PPP1R13B | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1407598003, COSV52448411; called by muse, mutect2, varscan2
- PPP1R26 | c.3290del p.G1097Afs*57 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs764146060; called by mutect2, varscan2
- PPP1R3D | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1457194568, COSV100674553, COSV100674720, COSV62564469; called by muse, mutect2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs768056539; called by mutect2, varscan2
- PPWD1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54333567; called by muse, mutect2, varscan2
- PRH1 | c.524del p.G175Afs*22 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as rs755190018; called by mutect2, pindel, varscan2
- PRPF4 | c.1264G>A p.A422T (on ENST00000374198 / NM_001322267.2; = p.A423T on NM_004697.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1206664579, COSV100950697; called by muse, mutect2, varscan2
- PRRX1 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99509776; called by muse, mutect2, varscan2
- PSMA1 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101123674; called by muse, mutect2, varscan2
- PSMB1 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100079879; called by muse, mutect2, varscan2
- PSPC1 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58889622; called by muse, mutect2, varscan2
- PTGR1 | c.19T>C p.W7R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99437364; called by muse, mutect2, varscan2
- PTPN2 | c.1021A>G p.M341V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs934635618, COSV100518586; called by muse, mutect2, varscan2
- PTPRM | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs140491606, COSV59865139; called by muse, mutect2, varscan2
- PTPRT | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100627861, COSV61981822; called by muse, mutect2
- PXDN | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751455151, COSV53227336, COSV99413727; called by muse, mutect2, varscan2
- PYGO2 | c.405del p.F136Sfs*25 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV100868881; called by mutect2, pindel, varscan2
- RAB11FIP2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100843065; called by muse, mutect2, varscan2
- RAB6C | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs747296971, COSV69339855; called by muse, mutect2, varscan2
- RAPGEF5 | c.356G>A p.C119Y (on ENST00000401957 / NM_001367602.2; = p.C422Y on NM_012294.5) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100687152; called by muse, mutect2
- RASAL1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs763097544, COSV55660550, COSV99921804; called by mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM43 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100508588; called by muse, mutect2, varscan2
- RBP3 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs145285304; called by muse, mutect2
- RBPJL | c.1372A>C p.S458R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100643509; called by muse, mutect2, varscan2
- RELCH | c.2648A>G p.Q883R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99902183; called by muse, mutect2, varscan2
- RELN | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.838); catalogued as COSV100633932; called by muse, mutect2, varscan2
- REN | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99689561; called by muse, mutect2, varscan2
- RFWD3 | c.1538T>C p.L513P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100736247; called by muse, mutect2, varscan2
- RIOK1 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV99344809; called by muse, mutect2
- RNASEL | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100842605; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF165 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs752024290, COSV99491740; called by mutect2, varscan2
- RNF213 | c.12331T>C p.C4111R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100300703; called by muse, mutect2, varscan2
- RNF32 | c.199del p.T67Lfs*7 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as rs771776056; called by mutect2, pindel, varscan2
- RNF43 | c.832_834del p.E278del | In Frame Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs1174509032; called by pindel, varscan2
- ROS1 | c.2117A>T p.N706I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100877153; called by muse, mutect2, varscan2
- RPS6KA6 | c.869T>A p.L290H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53116777, COSV53128576; called by muse, mutect2
- RSPH10B2 | c.33del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs868292826; called by mutect2, varscan2
- RTTN | c.5745G>A p.K1915= | Splice Region (SNP) | VAF 7/62 reads (11%) | catalogued as rs755262692, COSV99731296; called by muse, mutect2, varscan2
- RYR3 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101212911; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | catalogued as COSV59083791; called by mutect2, varscan2
- SAMHD1 | c.1410+2T>A p.X470_splice | Splice Site (SNP) | VAF 7/99 reads (7%) | catalogued as COSV99484099; called by muse, mutect2
- SAP30L | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as rs1421723663, COSV99770407; called by muse, mutect2, varscan2
- SARDH | c.2054T>C p.I685T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100898414; called by muse, mutect2, varscan2
- SCN9A | c.4915A>G p.M1639V (on ENST00000303354; = p.M1628V on NM_002977.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100313049; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC31A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs747567461, COSV52341196; called by muse, mutect2, varscan2
- SEMA6D | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240809744, COSV100317057; called by mutect2, varscan2
- SFTPA2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs369359980; called by muse, mutect2, varscan2
- SGCB | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs570232197, COSV67341000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGCE | c.1295A>G p.E432G (on ENST00000647096; = p.E396G on NM_003919.3) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99722641; called by muse, mutect2
- SGK2 | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100414679; called by muse, mutect2, varscan2
- SGSM1 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV101240824; called by muse, mutect2
- SIPA1L1 | c.4946G>T p.S1649I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.253); catalogued as COSV100665636; called by muse, mutect2, varscan2
- SIPA1L3 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55910540; called by muse, mutect2, varscan2
- SIPA1L3 | c.2444C>T p.T815I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV99729033; called by muse, mutect2, varscan2
- SLC16A3 | c.1060A>G p.S354G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100012457; called by muse, mutect2, varscan2
- SLC25A1 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.158); catalogued as COSV99310971; called by muse, mutect2, varscan2
- SLC25A40 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs766776279, COSV100353703; called by muse, mutect2
- SLC25A42 | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV100588083; called by mutect2, varscan2
- SLC28A2 | c.706T>A p.F236I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100754737; called by muse, varscan2
- SLC2A6 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs370809335; called by muse, mutect2, varscan2
- SLC35B4 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV101043110; called by muse, mutect2, varscan2
- SLC37A3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as rs561596536, COSV100405494, COSV58269429; called by muse, mutect2, varscan2
- SLC39A1 | c.233dup p.V79Rfs*13 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | catalogued as rs763102282; called by mutect2, pindel
- SLC6A13 | c.1414+1G>A p.X472_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV58260562; called by muse, mutect2, varscan2
- SLC6A15 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs376347410; called by muse, mutect2, varscan2
- SLITRK1 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as COSV65676792; called by muse, mutect2
- SLITRK4 | c.1892C>T p.T631M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs782534462, COSV62022405; called by muse, mutect2, varscan2
- SORBS2 | c.491C>T p.A164V (on ENST00000284776 / NM_021069.5; = p.A210V on NM_003603.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs139060966, COSV99511239; called by muse, mutect2, varscan2
- SOX10 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100704140; called by muse, mutect2, varscan2
- SPNS3 | c.1382del p.G461Afs*6 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs756918252; called by pindel, varscan2
- SPRED2 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710248; called by muse, mutect2, varscan2
- SRSF7 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100492679; called by muse, mutect2, varscan2
- SSH2 | c.4094T>C p.L1365S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.933); catalogued as COSV99282224; called by muse, mutect2, varscan2
- STIP1 | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534892; called by muse, mutect2, varscan2
- STK25 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148589164; called by muse, mutect2, varscan2
- STRN4 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs201535838, COSV99623702; called by muse, mutect2
- STS | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1233947671, COSV99481234; called by muse, mutect2, varscan2
- STT3B | c.655T>A p.S219T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99854332; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SUMO1 | c.208A>G p.R70G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV101108629; called by muse, mutect2, varscan2
- SYK | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101002489, COSV65325110; called by muse, mutect2, varscan2
- TAB1 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1222699707, COSV99336079; called by muse, varscan2
- TAB1 | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99336081; called by muse, varscan2
- TAF1C | c.1361del p.P454Lfs*14 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs749363736; called by mutect2, pindel
- TAP1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841225; called by muse, mutect2
- TARS2 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100945998; called by muse, mutect2, varscan2
- TAS2R40 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV101283004; called by muse, mutect2, varscan2
- TASP1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773637963, COSV61811246; called by muse, mutect2, varscan2
- TBC1D1 | c.3223A>G p.S1075G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99791408; called by muse, mutect2, varscan2
- TBC1D23 | c.1876C>T p.R626W (on ENST00000394144 / NM_001199198.3; = p.R611W on NM_018309.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1317132696, COSV100792628; called by muse, varscan2
- TBCEL | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99412204; called by muse, mutect2, varscan2
- TBL1X | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99482669, COSV99482670; called by muse, mutect2
- TBL3 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as rs763489728, COSV100224930; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as rs754897911; ClinVar: uncertain significance; called by pindel, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as rs745872748; called by mutect2, varscan2
- TGIF2LX | c.595T>C p.S199P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99383400; called by muse, mutect2
- TGM2 | c.12G>A p.E4= | Splice Region (SNP) | VAF 8/89 reads (9%) | catalogued as COSV100821650; called by muse, mutect2
- TGM7 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101476868; called by muse, mutect2
- TLN2 | c.5872G>A p.V1958I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as rs375769813; called by muse, mutect2, varscan2
- TLR7 | c.1521del p.F507Lfs*16 | Frame Shift Del (DEL) | VAF 26/195 reads (13%) | catalogued as rs764545107; called by mutect2, pindel, varscan2
- TM4SF20 | c.186C>A p.A62= | Splice Region (SNP) | VAF 46/244 reads (19%) | catalogued as COSV100460085; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs754390908; called by mutect2, varscan2
- TMEM176B | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100423565; called by muse, mutect2, varscan2
- TMEM250 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.962); catalogued as COSV101403414; called by muse, mutect2, varscan2
- TMEM60 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV99301831; called by muse, mutect2, varscan2
- TMPRSS6 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750274321, COSV60978533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFAIP2 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100280964; called by muse, mutect2, varscan2
- TNK1 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100294860; called by muse, mutect2
- TPR | c.3809A>C p.N1270T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100823981; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs752676391; called by mutect2, varscan2
- TRPM3 | c.4659C>A p.D1553E (on ENST00000357533 / NM_001366142.2; = p.D1408E on NM_020952.6) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100677519, COSV62589437; called by muse, mutect2, varscan2
- TRPV5 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV99520608; called by muse, mutect2, varscan2
- TSPYL2 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100212283; called by muse, mutect2
- TSR3 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.041); catalogued as COSV99136262; called by muse, mutect2, varscan2
- TTC21B | c.3103T>A p.Y1035N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV99692419; called by muse, mutect2
- TTN | c.77959G>A p.G25987R (on ENST00000591111; = p.G18563R on NM_003319.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | PolyPhen possibly damaging (0.748); catalogued as rs773909467, COSV100616087, COSV60041903; called by muse, mutect2, varscan2
- TUBA8 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV100283141; called by muse, varscan2
- UACA | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773114002, COSV100537551; called by mutect2, varscan2
- UNC13C | c.1505C>A p.S502* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV52916719, COSV99518229; called by muse, mutect2, varscan2
- UNC5B | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1253641274, COSV100100253; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs760213136; called by mutect2, varscan2
- USH1G | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1480501046, COSV100140284; called by muse, mutect2, varscan2
- USH2A | c.2444G>A p.C815Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236045; called by muse, mutect2, varscan2
- USP11 | c.2785C>T p.R929C (on ENST00000218348; = p.R886C on NM_001371072.1) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760876517, COSV54474099; called by muse, mutect2, varscan2
- USP12 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99997635; called by muse, mutect2, varscan2
- VPS13B | c.6795C>A p.Y2265* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100662217; called by muse, mutect2, varscan2
- VPS35 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV100140670; called by muse, mutect2, varscan2
- VPS45 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100964908; called by muse, mutect2, varscan2
- VWCE | c.2851del p.E951Kfs*33 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs770073614, COSV57111238; called by mutect2, pindel, varscan2
- WDR19 | c.2177T>C p.L726P | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99975566; called by muse, mutect2, varscan2
- WDR19 | c.2849C>A p.S950Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99975568; called by muse, mutect2, varscan2
- WDR33 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | catalogued as rs1297033169, COSV59246969; called by muse, mutect2
- WDR54 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV51965264; called by muse, mutect2, varscan2
- WDR62 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs908383011, COSV54332119; called by muse, mutect2, varscan2
- WNT9A | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs552502207, COSV55293545; called by muse, mutect2
- YPEL4 | c.384A>G p.*128Wext*54 | Nonstop Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100254242; called by mutect2, varscan2
- ZAP70 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99385592; called by muse, mutect2, varscan2
- ZBTB7B | c.1517C>T p.A506V (on ENST00000292176; = p.A540V on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99421243; called by muse, mutect2
- ZC3H13 | c.3424A>G p.T1142A | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs988028078, COSV99668258; called by muse, mutect2, varscan2
- ZDHHC16 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100620561, COSV100620625; called by muse, mutect2, varscan2
- ZFAT | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100914662; called by muse, mutect2, varscan2
- ZFHX4 | c.9604del p.I3202Sfs*6 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs1563570378; called by mutect2, pindel
- ZFP57 | c.529del p.C177Afs*25 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1272756745; called by mutect2, pindel, varscan2
- ZNF114 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV100252055; called by muse, mutect2, varscan2
- ZNF275 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.83); catalogued as COSV100936260, COSV100936286; called by muse, mutect2, varscan2
- ZNF277 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs760905735, COSV62463382; called by muse, mutect2, varscan2
- ZNF283 | c.988del p.W330Gfs*10 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs779648677; called by mutect2, pindel, varscan2
- ZNF287 | c.1518del p.K506Nfs*259 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | catalogued as COSV101209436; called by mutect2, pindel, varscan2
- ZNF334 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV100749103; called by muse, mutect2, varscan2
- ZNF404 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100182602; called by muse, mutect2, varscan2
- ZNF416 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs777089512, COSV99543845; called by muse, mutect2
- ZNF419 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs377557523; called by muse, mutect2, varscan2
- ZNF470 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100401257; called by mutect2, varscan2
- ZNF534 | c.508A>C p.T170P (on ENST00000332323 / NM_001143939.3; = p.T157P on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99989840; called by muse, mutect2, varscan2
- ZNF551 | c.84T>C p.G28= | Splice Region (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99990026; called by muse, mutect2, varscan2
- ZNF555 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs368059401; called by mutect2, varscan2
- ZNF584 | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs868790957, COSV100183317; called by muse, mutect2, varscan2
- ZNF587 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs771006222, COSV100299514, COSV57148364; called by muse, mutect2
- ZNF592 | c.1964C>A p.P655H | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100245899; called by muse, mutect2, varscan2
- ZNF600 | c.1911_1912del p.Y638Qfs*3 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs750558756; called by mutect2, pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF616 | c.618A>G p.I206M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs748000428; called by muse, mutect2, varscan2
- ZNF649 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.07); catalogued as rs1006713835, COSV56817771, COSV56818462; called by muse, mutect2, varscan2
- A2ML1 | c.1704del p.S569Pfs*39 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | called by mutect2, pindel, varscan2
- ADAM7 | c.1781del p.L594Yfs*29 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS15 | c.281del p.G94Afs*14 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- AL121899.2 | c.276_277del p.F93Sfs*7 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by pindel, varscan2
- ANKRD11 | c.831dup p.T278Hfs*71 | Frame Shift Ins (INS) | VAF 15/119 reads (13%) | called by mutect2, pindel, varscan2
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 19/112 reads (17%) | called by mutect2, pindel, varscan2
- BAZ1A | c.1840del p.M614* | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- BCL9 | c.468dup p.S157Lfs*27 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by pindel, varscan2
- BCOR | c.4862del p.P1621Qfs*53 (on ENST00000378444 / NM_001123385.2; = p.P1587Qfs*53 on NM_017745.6) | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- BMPER | c.1835_1836dup p.G613Rfs*81 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- BPIFB4 | c.620del p.G207Vfs*26 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- BTBD16 | c.906del p.F302Lfs*15 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- C20orf194 | c.219dup p.G74Wfs*9 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- CISH | c.164_167del p.E55Vfs*15 (on ENST00000348721 / NM_145071.4; = p.E72Vfs*15 on NM_013324.6) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- CLSTN2 | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.572); called by muse, mutect2
- COL11A2 | c.1292del p.P431Lfs*79 (on ENST00000341947 / NM_080680.3; = p.P324Lfs*79 on NM_080679.2) | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel
- COL5A1 | c.1081del p.E361Rfs*197 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- CTSV | c.821del p.N274Tfs*40 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- CYP2U1 | c.901del p.I301Sfs*18 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- DENND2B | c.218del p.P73Qfs*53 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- DEPTOR | c.902del p.P301Lfs*10 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- DEUP1 | c.1725del p.K575Nfs*3 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- DHRS7 | c.642del p.F214Lfs*14 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- DIDO1 | c.6367_6368del p.W2123Efs*133 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel
- DIP2A | c.3432del p.S1145Pfs*18 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- DLL1 | c.845del p.G282Afs*8 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- DYM | c.41del p.N14Mfs*4 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by pindel, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- EMC2 | c.745del p.T249Rfs*6 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- EPG5 | c.5704del p.Y1902Ifs*26 | Frame Shift Del (DEL) | VAF 11/103 reads (11%) | called by mutect2, pindel, varscan2
- EPRS1 | c.3648del p.F1216Lfs*10 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- FASTKD1 | c.10del p.T4Hfs*5 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- FAT3 | c.1409del p.P470Qfs*12 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- FN1 | c.6632_6633del p.T2211Sfs*9 (on ENST00000359671 / NM_001365524.2; = p.T2180Sfs*9 on NM_002026.4) | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2
- FXR2 | c.1619del p.P540Qfs*32 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, varscan2
- GAA | c.2366del p.P789Hfs*17 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- GPNMB | c.1002del p.K334Nfs*6 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- GPR158 | c.3366del p.A1124Lfs*2 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- GPR26 | c.829del p.V277Cfs*33 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- GPR75 | c.1196del p.F399Sfs*58 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | called by mutect2, pindel, varscan2
- GRIN3A | c.3142del p.L1048Sfs*21 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, varscan2
- HCN4 | c.1589dup p.Y531Vfs*55 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- HDLBP | c.538del p.T180Lfs*48 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- IARS2 | c.2681C>A p.P894H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IGDCC3 | c.2168del p.P723Rfs*37 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- IL10RA | c.905del p.L302* | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- IPO4 | c.1038dup p.E347Rfs*35 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- KIF9 | c.920dup p.N308Kfs*36 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- KMT2D | c.15976del p.M5327Wfs*6 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- KNL1 | c.5662-1_5662del p.X1888_splice (on ENST00000346991 / NM_170589.5; = p.X1862_splice on NM_144508.5) | Splice Site (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel
- KRTAP10-2 | c.282dup p.C95Lfs*31 | Frame Shift Ins (INS) | VAF 18/160 reads (11%) | called by pindel, varscan2
- LAMA1 | c.8555del p.N2852Ifs*13 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- LAP3 | c.506del p.K169Rfs*34 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- LARS1 | c.987del p.A330Qfs*23 (on ENST00000394434 / NM_020117.11; = p.A303Qfs*23 on NM_016460.3) | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- LEMD3 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- LRIT2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- LRRCC1 | c.3037del p.T1013Qfs*13 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- LTB4R2 | c.1043del p.G348Afs*17 (on ENST00000528054; = p.G317Afs*17 on NM_019839.5) | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- MACF1 | c.16338del p.K5446Nfs*54 (on ENST00000372915; = p.K3379Nfs*58 on NM_012090.5) | Frame Shift Del (DEL) | VAF 13/98 reads (13%) | called by mutect2, pindel, varscan2
- MAN1A2 | c.1367del p.K456Rfs*15 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- MAP1B | c.3115del p.M1039Wfs*7 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- MAP1LC3A | c.238_240del p.F80del | In Frame Del (DEL) | VAF 12/102 reads (12%) | called by pindel, varscan2
- MAP3K15 | c.2991del p.D997Efs*59 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- MCOLN2 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2
- MINPP1 | c.1322del p.K441Rfs*18 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- MON1A | c.696del p.R233Gfs*26 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- MPRIP | c.1090del p.L364Cfs*19 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by pindel, varscan2
- MTDH | c.871_872del p.V291Kfs*10 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- MYO1E | c.155_156del p.I52Rfs*22 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by pindel, varscan2
- MYOF | c.737del p.F246Sfs*6 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- NCOA2 | c.4050del p.S1351Pfs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.485del p.P162Qfs*6 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- NLGN4X | c.998dup p.A334Gfs*53 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- NOTCH1 | c.7020del p.S2341Pfs*7 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- NR1D1 | c.299dup p.G101Wfs*33 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by pindel, varscan2
- NRXN3 | c.2359del p.S787Afs*4 (on ENST00000335750 / NM_001330195.2; = p.S414Afs*4 on NM_004796.6) | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- OCIAD1 | c.696del p.E233Kfs*4 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- OR13C5 | c.84del p.F28Lfs*6 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- OR52I2 | c.399del p.F133Lfs*4 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- OR5T1 | c.122del p.L41Yfs*4 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- PLAA | c.1614del p.E539Rfs*14 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- PSENEN | c.172_173del p.W58Afs*62 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- RAB5A | c.338del p.N113Ifs*15 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- RBM15 | c.851del p.P284Lfs*98 | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | called by mutect2, pindel
- RNF5 | c.61dup p.A21Gfs*8 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- SDR16C5 | c.787del p.M263Cfs*12 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- SEMA3C | c.987-3del | Splice Region (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- SETX | c.2091dup p.T698Yfs*2 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- SFXN3 | c.853dup p.L285Pfs*27 | Frame Shift Ins (INS) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- SLC16A10 | c.844del p.I282Ffs*9 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- SLC23A2 | c.1836del p.K612Nfs*64 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- SLC30A9 | c.699del p.F233Lfs*8 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.252del p.F84Lfs*32 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- STARD13 | c.2889del p.S964Qfs*4 (on ENST00000336934 / NM_001243476.3; = p.S846Qfs*4 on NM_052851.3) | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- STAT5B | c.1749del p.K583Nfs*16 | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel, varscan2
- STAU2 | c.1090_1091del p.N364Cfs*12 (on ENST00000524300 / NM_001164380.2; = p.N332Cfs*12 on NM_014393.2) | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- TAF1 | c.2436del p.A813Pfs*14 (on ENST00000373790 / NM_138923.4; = p.A834Pfs*14 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- TCAIM | c.598del p.S200Vfs*6 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, varscan2
- TENM3 | c.2082del p.T695Rfs*81 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- TET1 | c.184del p.T62Qfs*13 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- TF | c.1970del p.L657Wfs*14 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- THSD7A | c.1608del p.G537Afs*4 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- TIAM2 | c.1516del p.V506Wfs*35 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- TMEM185A | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2
- TOPORS | c.966_968del p.I322del | In Frame Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- TRIM31 | c.744+1dup p.X248_splice | Splice Site (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- WNK1 | c.1492del p.I498* | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- YLPM1 | c.760_761del p.P254Wfs*3 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- YTHDF2 | c.404del p.G135Efs*26 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- ZBTB32 | c.15del p.I6* | Frame Shift Del (DEL) | VAF 22/131 reads (17%) | called by mutect2, pindel, varscan2
- ZFP90 | c.623dup p.K209Efs*4 | Frame Shift Ins (INS) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- ZNF140 | c.679A>G p.S227G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2
- ZNF292 | c.3470del p.L1157Cfs*5 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- ZNRF3 | c.2372del p.G791Afs*14 (on ENST00000544604 / NM_001206998.2; = p.G691Afs*14 on NM_032173.3) | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- ACHE | c.279T>C p.A93= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs895009390, COSV99574180; called by muse, mutect2, varscan2
- ACSS3 | c.984C>T p.Y328= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1349274299, COSV99698937; called by muse, mutect2, varscan2
- ADAM21 | c.1629T>C p.C543= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99961079; called by muse, mutect2, varscan2
- ADAM8 | c.1650C>T p.G550= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs780965691, COSV101291675; called by muse, mutect2, varscan2
- ADCY6 | c.3360G>A p.T1120= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs371765360, COSV57167059; called by muse, mutect2, varscan2
- ADGRG4 | c.1329C>T p.A443= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs749064564, COSV54953939, COSV54964276; called by muse, mutect2, varscan2
- ADGRL1 | c.684G>A p.E228= (on ENST00000340736 / NM_001008701.3; = p.E223= on NM_014921.5) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100529564; called by muse, mutect2
- AFAP1L2 | c.1836C>T p.T612= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs770242787, COSV58414225; called by muse, mutect2, varscan2
- AGBL1 | c.3312G>A p.L1104= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV101223296; called by muse, mutect2, varscan2
- ANKFY1 | c.528G>A p.E176= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100492770; called by muse, mutect2, varscan2
- ANXA3 | c.63A>G p.S21= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99363690, COSV99363753; called by muse, mutect2, varscan2
- APPL1 | c.1962T>C p.N654= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99897770; called by muse, mutect2
- ATP1A4 | c.1134G>A p.T378= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs200792972, COSV63626338, COSV63628666; called by muse, mutect2, varscan2
- BMP3 | c.1044G>A p.T348= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs778395597, COSV51100448; called by mutect2, varscan2
- BMPR1B | c.252T>G p.T84= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99215940; called by muse, mutect2, varscan2
- CABYR | c.1386T>C p.G462= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100510081; called by muse, mutect2, varscan2
- CAD | c.3666C>A p.S1222= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99255154; called by muse, mutect2, varscan2
- CAPN5 | c.1359G>A p.T453= (on ENST00000456580; = p.T413= on NM_004055.5) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs782428044, COSV99582240; called by muse, mutect2, varscan2
- CARS1 | c.1842C>T p.S614= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs375211080; called by muse, mutect2, varscan2
- CCDC88C | c.1884G>A p.E628= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs761074410, COSV66238033; called by mutect2, varscan2
- CD40LG | c.390C>T p.A130= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV65698645; called by muse, mutect2, varscan2
- CD93 | c.1104A>G p.E368= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs879796766, COSV99849271; called by muse, mutect2
- CDC42BPB | c.3678G>A p.V1226= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100775471; called by muse, mutect2, varscan2
- CDCA2 | c.1068T>G p.T356= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs965768961, COSV100398900; called by muse, mutect2, varscan2
- CDH11 | c.1230T>G p.P410= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99218624; called by muse, mutect2, varscan2
- CDH12 | c.1242C>T p.G414= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101202685; called by muse, mutect2, varscan2
- CDK5R1 | c.249T>C p.N83= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs748373515, COSV99912491; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1212G>A p.V404= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100621173; called by muse, mutect2, varscan2
- CDK6 | c.504C>T p.R168= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs771163287, COSV99721295; called by muse, mutect2, varscan2
- CHD6 | c.825A>G p.S275= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV100498340; called by muse, mutect2, varscan2
- CHRNA4 | c.1794C>T p.I598= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1365100603, COSV100937424; called by muse, mutect2, varscan2
- CHRNA7 | c.669A>G p.T223= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs370572702; called by mutect2, varscan2
- CMYA5 | c.11133A>G p.E3711= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV101484122; called by muse, mutect2, varscan2
- CNGB3 | c.1344T>C p.A448= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100182115; called by muse, mutect2, varscan2
- CNKSR2 | c.909A>T p.S303= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99668755, COSV99669825; called by muse, mutect2, varscan2
- COL5A2 | c.1278T>C p.G426= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100880418; called by muse, mutect2
- CSE1L | c.969A>C p.S323= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV53700317; called by muse, mutect2, varscan2
- CWF19L2 | c.2098T>C p.L700= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99979124; called by muse, mutect2
- DHX38 | c.786G>A p.S262= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1567604323, COSV99194269, COSV99194336; called by muse, mutect2, varscan2
- DMRTA1 | c.900G>A p.L300= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100364782; called by muse, mutect2, varscan2
- DNAH11 | c.4656T>C p.C1552= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100179434; called by muse, mutect2
- DNAH11 | c.12303C>T p.G4101= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100177191; called by muse, mutect2, varscan2
- DNAH3 | c.10533C>A p.S3511= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99767911; called by mutect2, varscan2
- DOCK8 | c.549C>T p.N183= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as rs752184508, COSV101210272; called by muse, mutect2, varscan2
- DPEP3 | c.813G>A p.S271= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs773026799, COSV52051305; called by muse, mutect2, varscan2
- DPY19L4 | c.1032T>C p.A344= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV101363318; called by muse, mutect2, varscan2
- DSG3 | c.1524C>T p.S508= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs754839133, COSV99933992; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1137A>G p.L379= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs771672471, COSV99818186; called by muse, mutect2
- EHD1 | c.189C>T p.L63= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100277068; called by muse, mutect2, varscan2
- EIF5 | c.300T>C p.P100= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs750013485, COSV99384861; called by mutect2, varscan2
- ETV3L | c.888G>T p.A296= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV101485594; called by muse, mutect2, varscan2
- EXTL3 | c.1626C>T p.A542= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs140625555; called by muse, mutect2, varscan2
- EZHIP | c.183C>T p.S61= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs782142139, COSV100539751; called by muse, mutect2, varscan2
- F10 | c.1047C>T p.A349= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs545046199, COSV100979217; called by muse, mutect2, varscan2
142 further variants in this file (0 protein-altering or splice-affecting, 127 silent, 15 other) are not listed here.
